Gene-level copy-number profile of tumor specimen TCGA-56-7579-01A from TCGA case TCGA-56-7579, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.0 years (22,632 days).
Specimen TCGA-56-7579-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.243fcf71-4de9-4b82-84a5-77c50d77e187.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-7579-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/82972e1f-7300-49e1-8318-7f19ddeb58cf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 19,416; copy number 2: 31,170; copy number 3: 8,243; copy number 4: 70; copy number 5: 20; copy number 6: 592; copy number 7: 213; copy number 8: 41; copy number 11: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-7579-01A-11D-2041-01): tumor purity 0.66, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:19,098,199–19,098,740, 1 gene: AC006840.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 909 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:84,638,405–86,074,429, 6 genes, copy number 5 (within-gene range 1–5): LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688.
- chr3:162,486,541–198,222,513, 645 genes, copy number 6–7 (broad region; genes not listed).
- chr6:47,781,982–50,913,256, 41 genes, copy number 8 (within-gene range 3–8): OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1, FTH1P5.
- chr8:32,440,704–39,580,134, 127 genes, copy number 6–11 (within-gene range 1–11) (broad region; genes not listed).
- chr8:40,369,981–43,378,510, 76 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr9:36,036,913–36,163,913, 2 genes, copy number 5 (within-gene range 1–5): RECK, GLIPR2.
- chr11:43,063,637–43,523,264, 12 genes, copy number 5: AC009643.2, AC009643.1, HNRNPKP3, API5, AC087276.2, Y_RNA, TTC17, AC087276.3, AC087276.1, RN7SKP287, PPIAP41, CTBP2P6.

Autosomal genes at a single copy (total copy number 1): 17,044. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
